Somatic mutation profile of tumor specimen MBCProject_0170_T1_WES (aliquot MBCProject_0170_T1_WES_1) from CMI case MBCProject_0170, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 39.5 years (14,415 days).
Specimen MBCProject_0170_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c76416c5-12fa-47d4-ac17-e0bff0c5001a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0170_SALIVA (Saliva), aliquot MBCProject_0170_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de972e2-549c-4ec5-a2e9-f0c57350a9d8

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, 5'UTR 3, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM120849, CM134998, COSV52681833, COSV52696302, COSV52721346, COSV53165479; called by muse, mutect2, varscan2
- ACKR3 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV56024129; called by muse, mutect2, varscan2
- ANGPT4 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1426019461; called by muse, mutect2
- ANXA2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs267604276; called by mutect2, varscan2
- CPS1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); catalogued as COSV51819059; called by muse, mutect2, varscan2
- KRT78 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58852827; called by muse, mutect2
- NDST1 | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as rs759249762; called by muse, mutect2
- PIK3R2 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV99717290; called by muse, mutect2, varscan2
- RPL18 | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50031586; called by muse, mutect2, varscan2
- SLC9A6 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100857893; called by mutect2, varscan2
- TAZ | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.754); catalogued as COSV100173403; called by muse, mutect2, varscan2
- TRIM51 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs992683016, COSV99792852; called by mutect2, varscan2
- YRDC | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as COSV65988675; called by muse, mutect2, varscan2
- CCDC86 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CDH1 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, varscan2
- CELSR2 | c.6025C>G p.R2009G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CELSR3 | c.729dup p.E244Rfs*60 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- DOP1B | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- DRG2 | c.954+1G>C p.X318_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- FAM83A | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- GPC6 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL28 | c.1451T>G p.V484G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE8B | c.30del p.Q11Rfs*4 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel
- PIGR | c.1217A>T p.K406M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SERPINH1 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SH3PXD2A | c.2230G>C p.A744P (on ENST00000369774 / NM_001365079.1; = p.A716P on NM_014631.2) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.397); called by mutect2, varscan2
- SLC8A3 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TAGLN | c.572C>G p.T191R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by mutect2, varscan2
- THSD1 | c.1818G>C p.R606S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by mutect2, varscan2
- ZC3H11A | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by mutect2, varscan2
- ADAMTS13 | c.1116C>G p.R372= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- CCL14 | c.219C>T p.S73= (on ENST00000618404 / NM_032963.4; = p.S89= on NM_032962.4) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs745662062; called by mutect2, varscan2
- CDH5 | c.987C>T p.Y329= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58520152; called by muse, mutect2, varscan2
- CST8 | c.249A>G p.E83= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- KIF1B | c.2169G>T p.L723= (on ENST00000377086 / NM_001365952.1; = p.L677= on NM_015074.3) | Silent (SNP) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- LIG1 | c.1224C>T p.F408= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PLAT | c.1389G>A p.L463= | Silent (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- PRSS36 | c.1707T>C p.P569= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.213C>T p.S71= (on ENST00000421990 / NM_001136042.2; = p.S53= on NM_025267.3) | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2, varscan2
- RGMA | c.1188C>T p.Y396= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs535938921, COSV61233707; called by muse, mutect2, varscan2
- TGFBR2 | c.624G>A p.K208= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- FBXO24 | c.-13A>C | 5'UTR (SNP) | VAF 7/53 reads (13%) | called by mutect2, varscan2
- MRGPRG | chr11:3221901 C>T | 5'Flank (SNP) | VAF 5/23 reads (22%) | catalogued as rs996247357; called by muse, mutect2, varscan2
- RPL23A | c.387-110G>C | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1188561428; called by muse, mutect2, varscan2
- SDHA | c.-20G>T | 5'UTR (SNP) | VAF 14/36 reads (39%) | catalogued as rs753335035; called by muse, varscan2
- ZNF615 | c.-253_-252del | 5'UTR (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
